Surgical pathology report (de-identified scan), TCGA case TCGA-XC-AA0X, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Albert Einstein Medical Center, specimen TCGA-XC-AA0X-01A (Primary Tumor).

[page 1 of 4]
MRN: [REDACTED]
Patient: [REDACTED]
Admission Date:
Ordering Physician:

Sex/DOB: Female
Discharge Date:

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

Final Diagnosis

A. LUNG, RIGHT LOWER LOBE, LOBECTOMY:

- INVASIVE AND IN SITU SQUAMOUS CELL CARCINOMA, 1.3 CM, SEE SYNOPTIC REPORT
- FOUR LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4)

B. LYMPH NODES, LEVEL 7, RESECTION:

- THREE LYMPH NODES NEGATIVE FOR MALIGNANCY (0/3)

C. LYMPH NODES, LEVEL 10, RESECTION:

- FOUR LYMPH NODES NEGATIVE FOR MALIGNANCY (0/4)

D. LUNG, RIGHT MIDDLE LOBE, WEDGE RESECTION:

- LUNG WITH EMPHYSEMATOUS CHANGES, ALVEOLAR HEMORRHAGE

E. LYMPH NODES, R4, RESECTION:

- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

F. LYMPH NODE, R2, RESECTION:

- ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1)

*ICD O-3
Carcinoma, squamous cell
Site: R Lung, lower lobe
8070/3
C84.3
JW 2/24/14*

(Electronic signature)
Verified:

Synoptic Report

SPECIMEN:

Lung

PROCEDURE:

Lobectomy

SPECIMEN INTEGRITY:

Intact

Printed by:
Copied to:
Distribute to:

Page 1 of 4

Print Date/Time:

Patient Locations:

[page 2 of 4]
MRN: [REDACTED]
Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

SPECIMEN LATERALITY:

Right

TUMOR SITE:

Lower lobe

TUMOR SIZE:

Greatest dimension: 1.3 cm

TUMOR FOCALITY:

Unifocal

HISTOLOGIC TYPE:

Squamous cell carcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

VISCERAL PLEURA INVASION:

Not identified

TUMOR EXTENSION:

Tumor involves main bronchus 2 cm or more distal to the carina

BRONCHIAL MARGIN:

Cannot be assessed

VASCULAR MARGIN:

Cannot be assessed

PARENCHYMAL MARGIN:

Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN:

Not applicable

CHEST WALL MARGIN:

Not applicable

TREATMENT EFFECT:

Not applicable

LYMPH-VASCULAR INVASION:

Not identified

PRIMARY TUMOR (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 13

Number involved: 0

DISTANT METASTASIS (pM):

Not applicable

Source of Specimen

- A Right Lower Lobe
- B Level 7
- C Level 10

[page 3 of 4]
MRN: [REDACTED]
Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

D Right Middle Lobe
E R4
F R2

Clinical Information

PRE-OP DIAGNOSIS: Lung cancer

POST-OP DIAGNOSIS: Same

TYPE OF PROCEDURE: Bronchoscopy, right VATS. Removal right lower lobe

Gross Description

Specimen is received in 6 parts:

A. The specimen is labeled "RIGHT LOWER LOBE" and is received unfixed. It consists of a lobe of the lung measuring 15 x 12 x 8 cm and weighing 280 g. The pleural surface is pink-purple and smooth and shows multiple anthracotic markings. The bronchial and vascular margins are stapled shut. The soft tissue margin of resection measuring 2 cm, 4 cm, 4.5 cm and 5 cm.

A 1.3 x 1.2 x 1.2 cm an ill-defined gray-tan mass is identified 2 cm away from the bronchial margin of resection and 3 cm away from the closest pleural surface. Pleural surface closest to the mass is covered with smooth surface without any papillary excrescences and is inked. Remaining portion of the lung shows dark red tan congested parenchyma without other lesions. At the hilum 0.7 x 0.7 x 0.5 cm and 0.6 x 0.6 x 0.5 cm lymph nodes are identified. Representative sections are submitted as follows:

A1 = bronchial and vascular margin of resection

A2 = soft tissue margin of resection

A3-A5 = mass, entirely submitted

A6 = random section of the lung

A7 = 2 lymph nodes

A8 = closest pleural surface to the mass.

B. The specimen is labeled "LEVEL VII" and is received in formalin. It consists of 3 black tan lymph nodes ranging from 0.5 x 0.5 x 0.3 - 0.6 x 0.5 x 0.3 cm. Entirely submitted in cassette B1.

C. The specimen is labeled "LEVEL X" and is received in formalin. It consists of 4 black tan lymph nodes measuring 0.5 x 0.4 x 0.2-0.8 x 0.5 x 0.3 cm. Entirely submitted in cassette C1

D. The specimen is labeled "RIGHT MIDDLE LOBE" and is received in formalin. It consists of a wedge shaped piece of lung tissue measuring 3.5 x 1 x 0.7 cm which 3.5 cm stapled margin of resection. In the center portion 1 x 0.7 x 0.5 cm irregular fragmented area is noted which is 0.3 cm away from the stapled margin of resection which is inked red. Entirely submitted in cassettes D1-D2.

E. The specimen is labeled "R4" and is received in formalin. It consists of a single black lymph node measuring 2 x 0.7 x 0.6 cm. Sectioned and entirely submitted in cassette E1.

F. The specimen is labeled "R2" and is received in formalin. It consists of a single black tan lymph node measuring 0.7 x 0.5 x 0.5

[page 4 of 4]
MRN: [REDACTED]
Patient: [REDACTED]

Sex/DOB: Female [REDACTED]

Surgical Pathology Report

Collected Date/Time:
Received Date/Time:

Accession Number: [REDACTED]

cm. Sectioned and entirely submitted in cassette F1.

Dictated by:

Special Stains / Slides

TTF-1: negative in tumor cells.

Napsin A: negative in tumor cells.

p63: positive in tumor cells.

INTERPRETATION: Squamous cell carcinoma.

Immunohistochemical studies were performed on formalin fixed, paraffin-embedded tissue (Block A3) with adequate positive and negative control sections.

The performance characteristics of these antibodies were determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high-complexity clinical laboratory testing.

14 H&E, 3ihc

Tissue Code

Source: NCI Genomic Data Commons file e8a876e7-809c-4992-9da4-0f17f843b6b1 (TCGA-XC-AA0X.B22BD117-8DF0-47FF-BE25-9FE2DA916DB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).